CCDI case PBCAWP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0b1da011-f7ec-476f-9f8e-1e44ffd4ca1f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (140 days).

Biospecimens (3 samples)
- Sample 0DMUXG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMUY3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMUZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
